Somatic mutation profile of tumor specimen 0DRPJ3 from CCDI case PBCGVF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 14.0 years (5,121 days).
Specimen 0DRPJ3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e03ba6e-6001-411f-9e9f-fd4c7654918b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRPJA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2accba1-4f31-4f31-b413-b16ba78e43ec

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP2B1 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 356/967 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52004893; called by muse, mutect2, varscan2
- HDAC3 | c.1059G>A p.Q353= | Splice Region (SNP) | VAF 33/1053 reads (3%) | called by muse, mutect2
- MAP3K4 | c.3380G>A p.G1127D | Missense Mutation (SNP) | VAF 355/982 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRD | c.3506T>A p.L1169Q | Missense Mutation (SNP) | VAF 18/507 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- LONP2 | c.687A>G p.Q229= | Silent (SNP) | VAF 266/850 reads (31%) | catalogued as rs760497691; called by muse, mutect2, varscan2
- CHMP1A | c.*179C>T | 3'UTR (SNP) | VAF 82/405 reads (20%) | catalogued as rs754579486, COSV53682066; called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 24/710 reads (3%) | called by muse, mutect2
